Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9EK, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9EK-01A (Primary Tumor).

ICD 0-3
Melanoma, spindle cell
Site @ Choroid 8772/3
C69.3
QW 3/10/14

Macros copy

Microscopy

Conclusion

Melanoma with fusiform cells measuring 18 by 12 mm main lines.

The tumor infiltrates in front the posterior part of the ciliary body. Behind, the proliferation stays distant from the intraocular emergence of the optic nerve which is free on its entire course (prelamina part, optic foramen, post lamina part , meningeal sheaths and posterior cut end.)

The tumor proliferation infiltrates the internal layers of the sclera but no extra sclera extension was found.

[illegible]

Source: NCI Genomic Data Commons file bd7e5dfb-943c-44a1-b116-3bf2ab39bbbd (TCGA-V4-A9EK.9495F79F-3227-454F-942C-05CEC78273B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).